Somatic mutation profile of tumor specimen TCGA-AR-A2LE-01A (aliquot TCGA-AR-A2LE-01A-11D-A17W-09) from TCGA case TCGA-AR-A2LE, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 69.8 years (25,499 days).
Specimen TCGA-AR-A2LE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68a1991c-ec4b-4b95-90f8-ab821a600b55.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A2LE-10A (Blood Derived Normal), aliquot TCGA-AR-A2LE-10A-01D-A17W-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df84b427-7398-4c91-a877-0e0395b73c89

The open-access MAF lists 316 somatic variants for this specimen: 228 protein-altering or splice-affecting, 80 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 198, Silent 80, Nonsense Mutation 25, RNA 5, Frame Shift Del 2, Intron 2, Splice Region 1, Frame Shift Ins 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AAK1 | c.2488G>C p.E830Q | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.932); catalogued as COSV68643331; called by muse, mutect2, varscan2
- ABT1 | c.463C>T p.H155Y | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1561910263, COSV51291077; called by muse, mutect2, varscan2
- ADAM15 | c.1792C>G p.L598V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.506); catalogued as COSV55126327; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1765G>A p.E589K | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.2); catalogued as COSV52814162; called by muse, mutect2, varscan2
- ADCY10 | c.579C>G p.C193W | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63240143; called by muse, mutect2, varscan2
- ADCY10 | c.252G>A p.E84= | Splice Region (SNP) | VAF 22/108 reads (20%) | catalogued as COSV63240150, COSV63241597; called by muse, mutect2, varscan2
- ADCY10 | c.162G>A p.M54I | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV100897176, COSV63240158; called by muse, mutect2, varscan2
- ADCY9 | c.1410C>G p.I470M | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.954); catalogued as COSV53574316; called by muse, mutect2, varscan2
- AHCY | c.243C>G p.I81M | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV54153030; called by muse, mutect2, varscan2
- AK3 | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63346599; called by muse, mutect2, varscan2
- ANXA1 | c.428C>T p.S143L | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV57411071; called by muse, mutect2, varscan2
- APH1A | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV52528642; called by muse, mutect2, varscan2
- ARFIP2 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV54446599; called by muse, mutect2, varscan2
- ARHGEF37 | c.1537G>A p.V513M | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV100382113; called by muse, mutect2
- ARID1A | c.2132C>G p.S711* | Nonsense Mutation (SNP) | VAF 26/65 reads (40%) | catalogued as COSV61376007; called by muse, mutect2, varscan2
- ARMC4 | c.929C>G p.S310C | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); catalogued as COSV53464480; called by muse, mutect2, varscan2
- ASB12 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV62856257, COSV62856623; called by muse, mutect2, varscan2
- ASPM | c.3475G>A p.D1159N | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs1195820450, COSV54128586; called by muse, varscan2
- ASXL3 | c.1846G>C p.E616Q | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.767); catalogued as COSV52463758; called by muse, mutect2, varscan2
- ATF6 | c.1429C>T p.L477F | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV63407148; called by muse, mutect2, varscan2
- ATRX | c.2156C>G p.S719C | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV64875166, COSV64883207; called by muse, mutect2, varscan2
- ATXN7 | c.1609G>C p.D537H | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55750067; called by muse, mutect2, varscan2
- BIRC6 | c.6134C>T p.S2045F | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as COSV70198376; called by muse, mutect2, varscan2
- BIRC6 | c.12584G>T p.G4195V | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV70198381; called by muse, mutect2, varscan2
- BLM | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.033); catalogued as COSV100757213; called by muse, mutect2, varscan2
- BLM | c.793G>C p.E265Q | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.272); catalogued as COSV61923628; called by muse, varscan2
- BRWD1 | c.614C>T p.S205L | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV58122571; called by muse, mutect2, varscan2
- C12orf40 | c.1465G>C p.D489H | Missense Mutation (SNP) | VAF 69/185 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV61131452, COSV61137981; called by muse, mutect2, varscan2
- C2orf42 | c.1651G>C p.E551Q | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV52449879; called by muse, mutect2, varscan2
- CABLES1 | c.1893G>C p.Q631H (on ENST00000256925 / NM_001100619.2; = p.Q366H on NM_138375.2) | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV56932735; called by muse, mutect2, varscan2
- CAPN10 | c.252G>C p.K84N | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54376113; called by muse, mutect2, varscan2
- CCNI2 | c.671G>A p.G224D | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.442); catalogued as rs1192078740, COSV66394193; called by muse, mutect2, varscan2
- CD1A | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs139349958; called by muse, mutect2, varscan2
- CD226 | c.848G>A p.R283K | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs533971919, COSV54613426, COSV99711124; called by muse, mutect2
- CDC42BPB | c.2815G>A p.D939N | Missense Mutation (SNP) | VAF 60/387 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.189); catalogued as COSV63474708; called by muse, mutect2, varscan2
- CDC73 | c.1034C>A p.S345Y | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.949); catalogued as COSV66466503; called by muse, mutect2, varscan2
- CDH1 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 30/56 reads (54%) | catalogued as COSV55727283; called by muse, mutect2, varscan2
- CDK5RAP2 | c.754G>T p.E252* | Nonsense Mutation (SNP) | VAF 87/193 reads (45%) | catalogued as COSV62573681; called by muse, mutect2, varscan2
- CDKL1 | c.151C>T p.R51W | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1211043428, COSV53579164, COSV53582240; called by muse, mutect2, varscan2
- CDKN1A | c.293C>G p.S98* | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | catalogued as COSV55188588, COSV55190422; called by muse, mutect2, varscan2
- CENPI | c.1358C>T p.S453L | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); catalogued as COSV54501919; called by muse, mutect2, varscan2
- CEP104 | c.2460C>G p.F820L | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV65517096; called by muse, mutect2, varscan2
- CEP170 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 33/230 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.035); catalogued as COSV100317087; called by muse, mutect2, varscan2
- CHIT1 | c.1192G>C p.E398Q | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as COSV55146563; called by muse, mutect2, varscan2
- CKMT1A | c.1102G>C p.D368H | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63256767; called by muse, mutect2, varscan2
- CLASP2 | c.4508G>T p.G1503V (on ENST00000359576; = p.G1502V on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.084); catalogued as COSV56280795; called by muse, mutect2, varscan2
- CNOT1 | c.2692G>A p.E898K | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55315689; called by muse, mutect2, varscan2
- COX6A1 | c.31C>T p.R11W | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.328); catalogued as COSV57569321; called by muse, mutect2, varscan2
- CSDE1 | c.1351G>C p.E451Q (on ENST00000358528 / NM_001007553.3; = p.E420Q on NM_007158.6) | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.153); catalogued as COSV54744764; called by muse, mutect2, varscan2
- CUBN | c.2128G>A p.G710R | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64713994; called by muse, mutect2, varscan2
- CYB5R1 | c.390G>T p.K130N | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65916900; called by muse, mutect2, varscan2
- DAB1 | c.1295C>G p.S432* (on ENST00000371231; = p.S399* on NM_021080.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 37/88 reads (42%) | catalogued as COSV64692341, COSV64692439; called by muse, mutect2, varscan2
- DCAF6 | c.2527G>T p.E843* (on ENST00000312263 / NM_001349778.1; = p.E863* on NM_018442.3 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 56/187 reads (30%) | catalogued as COSV56577788; called by muse, mutect2, varscan2
- DCHS1 | c.7900C>T p.H2634Y | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as rs752182015, COSV54997059; called by muse, mutect2, varscan2
- DCHS1 | c.5905C>G p.L1969V | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.344); catalogued as rs1316855294, COSV100202048; called by muse, mutect2
- DCP1A | c.1672G>A p.D558N | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53688358; called by muse, mutect2, varscan2
- DENND5A | c.1243C>T p.L415F | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV60233092; called by muse, mutect2, varscan2
- DIAPH2 | c.1837C>T p.P613S | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV100230484, COSV61260565; called by muse, mutect2, varscan2
- DPEP3 | c.480G>C p.Q160H | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV52051098; called by muse, mutect2, varscan2
- DPP6 | c.1048G>T p.E350* (on ENST00000377770 / NM_001364500.2; = p.E288* on NM_001936.5) | Nonsense Mutation (SNP) | VAF 37/97 reads (38%) | catalogued as COSV100124730, COSV59608552; called by muse, mutect2, varscan2
- EMC4 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.912); catalogued as COSV50784637; called by muse, mutect2, varscan2
- ERCC6 | c.2467C>A p.P823T | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as COSV63389475; called by muse, mutect2, varscan2
- ETV5 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60501303; called by muse, mutect2, varscan2
- FAM47A | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV60495954; called by muse, mutect2, varscan2
- FAT4 | c.13955C>A p.S4652* | Nonsense Mutation (SNP) | VAF 24/55 reads (44%) | catalogued as COSV58680974, COSV58701419; called by muse, mutect2, varscan2
- FBP1 | c.145G>C p.V49L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as COSV64689211; called by muse, varscan2
- FKBP5 | c.31G>T p.E11* | Nonsense Mutation (SNP) | VAF 81/249 reads (33%) | catalogued as COSV61881322; called by muse, mutect2, varscan2
- FKBP9 | c.1705G>C p.E569Q | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54230205; called by muse, mutect2, varscan2
- FLG | c.2708G>C p.R903T | Missense Mutation (SNP) | VAF 70/474 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs769479426, COSV64240633; called by muse, mutect2, varscan2
- FMN2 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs1196521273, COSV60427416; called by muse, mutect2, varscan2
- FMOD | c.102G>C p.Q34H | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.4); catalogued as COSV61609912; called by muse, mutect2, varscan2
- FRS2 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV100166389, COSV54725009; called by muse, mutect2, varscan2
- FSCB | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.66); catalogued as rs759355542, COSV61217661; called by muse, mutect2, varscan2
- GNPAT | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 57/233 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1181082971, COSV64153308; called by muse, mutect2, varscan2
- GPAT4 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 65/101 reads (64%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV67840703; called by muse, mutect2, varscan2
- GPR180 | c.481G>C p.D161H | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65385454; called by muse, mutect2, varscan2
- H4C2 | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); catalogued as COSV55138496; called by muse, mutect2, varscan2
- HECW2 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53657003; called by muse, mutect2, varscan2
- IFNA21 | c.551G>C p.R184T | Missense Mutation (SNP) | VAF 61/163 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as rs577616759, COSV66518354; called by muse, mutect2, varscan2
- IGFBPL1 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.926); catalogued as rs1163390413, COSV66618010; called by muse, mutect2, varscan2
- IGSF9 | c.304G>T p.D102Y | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV63639763; called by muse, varscan2
- IHH | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55393110; called by muse, varscan2
- IHH | c.116G>C p.R39P | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV55393117, COSV99838815; called by muse, varscan2
- IL1RL2 | c.1397C>T p.S466L | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV51814660; called by muse, mutect2, varscan2
- IL2RB | c.134C>G p.S45C | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53425975; called by muse, mutect2, varscan2
- IPP | c.1472G>C p.G491A | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100739557; called by muse, varscan2
- IPP | c.1415G>C p.G472A | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as COSV100739562; called by muse, varscan2
- IRAK1 | c.1263G>C p.Q421H | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV64110710; called by muse, mutect2, varscan2
- JADE1 | c.86C>G p.S29C | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV56905473; called by muse, mutect2, varscan2
- KCNT2 | c.2024C>T p.S675F | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.56); catalogued as COSV54075605; called by muse, mutect2, varscan2
- KDM5B | c.1488C>G p.F496L | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52507045; called by muse, mutect2, varscan2
- KIAA1109 | c.6592G>A p.D2198N | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV52669854; called by muse, mutect2, varscan2
- KIF15 | c.1098G>C p.K366N | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV58160063; called by muse, mutect2, varscan2
- KRTAP10-4 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs782450087, COSV59949971; called by muse, mutect2, varscan2
- LAMC3 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); catalogued as rs1010124787, COSV63088819; called by muse, mutect2, varscan2
- LCE1E | c.122C>G p.S41C | Missense Mutation (SNP) | VAF 30/181 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.785); catalogued as COSV64219734, COSV64220090; called by muse, mutect2, varscan2
- LRBA | c.1960C>G p.L654V | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV100842054, COSV63953687; called by muse, mutect2, varscan2
- LRGUK | c.2281G>C p.E761Q | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as COSV53637020; called by muse, mutect2, varscan2
- LRGUK | c.2384C>T p.S795F | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.125); catalogued as COSV53637030; called by muse, mutect2, varscan2
- LRRIQ1 | c.4309G>A p.E1437K | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as rs1473157934, COSV67825469, COSV67829538; called by muse, mutect2, varscan2
- MADD | c.3976G>A p.D1326N | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as COSV60623237; called by muse, mutect2, varscan2
- MAGEA12 | c.929G>C p.R310T | Missense Mutation (SNP) | VAF 65/146 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV63294585; called by muse, mutect2, varscan2
- MAGI3 | c.655C>G p.Q219E | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as COSV56833664; called by muse, mutect2, varscan2
- MAMDC4 | c.3202G>A p.E1068K (on ENST00000445819; = p.E989K on NM_206920.3) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.866); catalogued as COSV56375441; called by muse, mutect2, varscan2
- MAP9 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.225); catalogued as COSV100250901; called by muse, mutect2
- MDC1 | c.3787G>C p.E1263Q | Missense Mutation (SNP) | VAF 62/157 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.291); catalogued as COSV64524286; called by muse, mutect2, varscan2
- MFAP5 | c.316C>T p.H106Y | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV100848111, COSV63945228; called by muse, mutect2, varscan2
- MINAR1 | c.1966G>A p.D656N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.494); catalogued as COSV59582341; called by muse, mutect2, varscan2
- MMAA | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV55579798; called by muse, mutect2, varscan2
- MORN3 | c.11C>G p.S4C | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.237); catalogued as COSV62507230; called by muse, mutect2, varscan2
- MROH2B | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV68183164; called by muse, mutect2, varscan2
- MRPS12 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55499282; called by muse, mutect2, varscan2
- MTF1 | c.2060C>T p.S687L | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.015); catalogued as COSV65988844; called by muse, mutect2, varscan2
- MUC16 | c.42582G>T p.Q14194H | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.878); catalogued as rs766446620, COSV66689460, COSV66691422; called by muse, mutect2, varscan2
- MYH9 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 55/181 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.345); catalogued as rs1569535680, COSV53385190; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYL5 | c.137G>C p.R46P | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV58519939; called by muse, mutect2, varscan2
- MYO15A | c.8535C>G p.I2845M | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52755497; called by muse, varscan2
- MYO16 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV51786160; called by muse, mutect2, varscan2
- NAA30 | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1224102042, COSV53648467; called by muse, mutect2, varscan2
- NAGK | c.872G>C p.R291T | Missense Mutation (SNP) | VAF 66/148 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as COSV54903384, COSV99730683; called by muse, mutect2, varscan2
- NCOR1 | c.1083-1G>A p.X361_splice | Splice Site (SNP) | VAF 6/17 reads (35%) | catalogued as COSV51971681; called by muse, mutect2, varscan2
- NEK1 | c.2611G>A p.E871K | Missense Mutation (SNP) | VAF 86/219 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.164); catalogued as COSV101455730, COSV71455680, COSV71458137; called by muse, mutect2, varscan2
- NFATC1 | c.1337G>A p.G446D | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53699049; called by muse, mutect2, varscan2
- NFKBIZ | c.2083G>A p.D695N | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.914); catalogued as COSV58200072; called by muse, mutect2, varscan2
- NIPA1 | c.240G>C p.Q80H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61679766; called by muse, mutect2, varscan2
- NIPBL | c.4237C>T p.Q1413* | Nonsense Mutation (SNP) | VAF 21/57 reads (37%) | catalogued as CM076352, COSV56949493; called by muse, mutect2, varscan2
- NMRK2 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.27); catalogued as rs1245228209; called by muse, mutect2
- NPAS1 | c.1324C>T p.P442S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as rs1255183902, COSV53409181; called by muse, mutect2, varscan2
- NR4A3 | c.998A>G p.N333S | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.349); catalogued as COSV58244607; called by muse, mutect2, varscan2
- NTN4 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.571); catalogued as rs762563540, COSV59219018; called by muse, mutect2, varscan2
- OAS3 | c.2035G>A p.E679K | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.622); catalogued as COSV57445266; called by muse, mutect2, varscan2
- OBSCN | c.3453G>T p.Q1151H | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV52769016, COSV99478081; called by muse, mutect2
- OPN1SW | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | catalogued as COSV50821587; called by muse, mutect2, varscan2
- OR2A4 | c.829C>T p.H277Y | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV59575836; called by muse, mutect2, varscan2
- OR6N1 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV58648057; called by muse, mutect2, varscan2
- OSBPL11 | c.1954G>A p.D652N | Missense Mutation (SNP) | VAF 57/167 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV56173688; called by muse, mutect2, varscan2
- PAN3 | c.2433G>T p.L811F | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56702671; called by muse, mutect2, varscan2
- PAPLN | c.2242C>G p.H748D (on ENST00000554301; = p.H721D on NM_173462.4) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV53716713; called by muse, mutect2, varscan2
- PASK | c.2867C>T p.S956F | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52149037, COSV52151498; called by muse, mutect2, varscan2
- PAX5 | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.885); catalogued as COSV63906754; called by muse, mutect2
- PCDHA2 | c.499C>T p.L167F | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.406); catalogued as COSV65366403; called by muse, mutect2, varscan2
- PCDHB2 | c.2386G>A p.E796K | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.028); catalogued as rs531551073, COSV50569843; called by muse, mutect2, varscan2
- PCDHGA2 | c.1567G>C p.E523Q | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53918466, COSV53933002; called by muse, mutect2, varscan2
- PCDHGA6 | c.1303G>T p.E435* | Nonsense Mutation (SNP) | VAF 19/40 reads (48%) | catalogued as COSV53933042; called by muse, mutect2, varscan2
- PCLO | c.5080G>C p.D1694H | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61629669; called by muse, mutect2, varscan2
- PCNT | c.4935G>C p.Q1645H | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.034); catalogued as rs145430819; called by muse, varscan2
- PEG3 | c.2945C>T p.S982F | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.509); catalogued as COSV55631191; called by muse, mutect2, varscan2
- PEX6 | c.2164C>T p.Q722* | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as rs1395477387, COSV55102792; called by muse, mutect2, varscan2
- PHC2 | c.222C>A p.Y74* | Nonsense Mutation (SNP) | VAF 4/48 reads (8%) | catalogued as COSV99931076; called by muse, mutect2
- PIGO | c.2899C>T p.Q967* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as COSV53053406; called by muse, mutect2, varscan2
- PLEKHA7 | c.1871C>T p.S624L | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.323); catalogued as COSV63045535; called by muse, mutect2, varscan2
- PLEKHG1 | c.1646C>T p.P549L | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs768747492, COSV62046869; called by muse, mutect2, varscan2
- PLEKHH2 | c.3515C>T p.S1172F | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as COSV56752465; called by muse, mutect2, varscan2
- PLEKHN1 | c.25C>T p.Q9* | Nonsense Mutation (SNP) | VAF 19/32 reads (59%) | catalogued as COSV58531476; called by muse, mutect2, varscan2
- POTEH | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 50/301 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.555); catalogued as rs760807244, COSV58882143; called by muse, mutect2, varscan2
- PPP1R14B | c.435G>C p.Q145H | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as rs1382019647, COSV58587818; called by muse, mutect2, varscan2
- PPP1R15A | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV52338745; called by muse, mutect2, varscan2
- PRAMEF2 | c.368C>G p.S123C | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.957); catalogued as rs773137790, COSV99535293; called by muse, mutect2
- PRB3 | c.115C>T p.R39* | Nonsense Mutation (SNP) | VAF 98/272 reads (36%) | catalogued as rs533793961, COSV54389356; called by muse, mutect2, varscan2
- PRH1 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 25/186 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.315); catalogued as COSV101457494; called by muse, varscan2
- PRH2 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.015); catalogued as rs763664759, COSV101113307; called by muse, mutect2, varscan2
- PRKCH | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.941); catalogued as COSV60647623, COSV60649644; called by muse, mutect2, varscan2
- PSME4 | c.1150G>C p.D384H | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.399); catalogued as COSV66364595; called by muse, mutect2, varscan2
- PUM2 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs761103124, COSV57579946; called by muse, mutect2, varscan2
- RACGAP1 | c.1838G>C p.S613T | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV56698565, COSV56698770, COSV56699089; called by muse, mutect2, varscan2
- RAD23B | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV63658203; called by muse, mutect2, varscan2
- RAD54B | c.1972C>T p.R658* | Nonsense Mutation (SNP) | VAF 26/82 reads (32%) | catalogued as rs1007531071, COSV60250833; called by muse, mutect2, varscan2
- RALB | c.68G>A p.G23E | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.767); catalogued as COSV55601735, COSV55602705, COSV55602728; called by muse, mutect2, varscan2
- RAPGEF5 | c.616C>T p.H206Y (on ENST00000401957 / NM_001367602.2; = p.H509Y on NM_012294.5) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0.017); catalogued as COSV59781677; called by muse, mutect2, varscan2
- RPS6KC1 | c.2629G>A p.E877K | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.111); catalogued as COSV65298666; called by muse, mutect2, varscan2
- RYR3 | c.6106G>T p.E2036* | Nonsense Mutation (SNP) | VAF 29/93 reads (31%) | catalogued as COSV66785642; called by muse, mutect2, varscan2
- SAGE1 | c.1501G>C p.D501H | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.614); catalogued as COSV100187254, COSV61013092; called by muse, mutect2
- SCN1A | c.4695G>C p.Q1565H (on ENST00000303395 / NM_001202435.3; = p.Q1554H on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV57667791; called by muse, mutect2, varscan2
- SEC61A1 | c.1157C>T p.S386F | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54576843; called by muse, mutect2, varscan2
- SEMA3D | c.2274G>C p.K758N | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV52391816, COSV52392691; called by muse, mutect2, varscan2
- SENP7 | c.3009C>A p.F1003L | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as COSV58611013; called by muse, mutect2, varscan2
- SLC10A5 | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.666); catalogued as COSV101594262, COSV72828320; called by muse, mutect2, varscan2
- SLC15A1 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.036); catalogued as rs199996553; called by muse, mutect2, varscan2
- SLC18A1 | c.356C>G p.S119* | Nonsense Mutation (SNP) | VAF 71/120 reads (59%) | catalogued as COSV52347709; called by muse, mutect2, varscan2
- SLC25A43 | c.862G>C p.E288Q | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54217579, COSV54217922; called by muse, mutect2, varscan2
- SLC35D2 | c.576G>C p.Q192H | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV53562611; called by muse, mutect2, varscan2
- SLC5A3 | c.163C>G p.L55V | Missense Mutation (SNP) | VAF 65/163 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62969204; called by muse, mutect2, varscan2
- SOX13 | c.21C>G p.I7M | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.027); catalogued as COSV65826630; called by muse, mutect2, varscan2
- SPEN | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65360861; called by muse, mutect2, varscan2
- SPTBN5 | c.5554C>T p.Q1852* | Nonsense Mutation (SNP) | VAF 25/76 reads (33%) | catalogued as COSV100310635, COSV58019583; called by muse, mutect2, varscan2
- SSH3 | c.1309G>C p.E437Q | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.472); catalogued as COSV57384410, COSV57385208; called by muse, mutect2, varscan2
- STARD5 | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as COSV57154419, COSV57154714; called by muse, mutect2, varscan2
- STK40 | c.496G>C p.E166Q | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); catalogued as COSV100828609; called by muse, mutect2, varscan2
- SYNE2 | c.15939G>C p.L5313F | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59947890; called by muse, mutect2, varscan2
- SYT16 | c.1471C>T p.H491Y | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.08); catalogued as rs748021480, COSV70856218; called by muse, mutect2, varscan2
- SYT6 | c.929G>A p.R310H (on ENST00000610222 / NM_001366225.1; = p.R225H on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776030947, COSV65772550; called by muse, mutect2, varscan2
- TAB3 | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV55836323; called by muse, mutect2, varscan2
- TAOK3 | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.805); catalogued as COSV100700388, COSV62401822; called by muse, varscan2
- TARS2 | c.1946C>G p.S649C | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV60872735; called by muse, mutect2, varscan2
- TET2 | c.2147C>T p.S716L | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as rs1169754208, COSV54407657, COSV54418966; called by muse, mutect2, varscan2
- TGFBR1 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.028); catalogued as rs1368326650, COSV66625539; called by muse, mutect2, varscan2
- THADA | c.2731C>G p.L911V | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57681882; called by muse, mutect2, varscan2
- TIAM2 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as rs182530977, COSV59692314; called by muse, mutect2, varscan2
- TMEM67 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.132); catalogued as COSV60038440; called by muse, mutect2, varscan2
- TMPO | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.321); catalogued as COSV54122774; called by muse, mutect2, varscan2
- TNMD | c.43C>G p.L15V | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.636); catalogued as COSV65977076; called by muse, mutect2, varscan2
- TRAPPC8 | c.520C>T p.Q174* | Nonsense Mutation (SNP) | VAF 32/105 reads (30%) | catalogued as COSV51970048; called by muse, mutect2, varscan2
- TSHZ2 | c.2692C>T p.H898Y | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61588335; called by muse, mutect2, varscan2
- TSPYL5 | c.1228C>T p.Q410* | Nonsense Mutation (SNP) | VAF 46/124 reads (37%) | catalogued as rs1205460708, COSV59071443; called by muse, mutect2, varscan2
- TTC30B | c.751G>A p.V251M | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs757138703, COSV68809387; called by muse, mutect2, varscan2
- TTN | c.80664del p.N26888Kfs*9 (on ENST00000591111; = p.N19464Kfs*9 on NM_003319.4) | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | catalogued as COSV60002004; called by mutect2, pindel, varscan2
- TTN | c.39266C>G p.S13089C (on ENST00000591111; = p.S5665C on NM_003319.4) | Missense Mutation (SNP) | VAF 23/67 reads (34%) | PolyPhen benign (0); catalogued as COSV60002023; called by muse, mutect2, varscan2
- UGGT2 | c.4330C>T p.P1444S | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65074150; called by muse, mutect2, varscan2
- UHRF1BP1L | c.2903C>G p.S968* | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as COSV54436564; called by muse, mutect2, varscan2
- USP28 | c.743C>T p.S248L | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV50159749; called by muse, mutect2, varscan2
- USP53 | c.2362G>A p.E788K | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.551); catalogued as rs749089898, COSV56793922; called by muse, mutect2, varscan2
- WTIP | c.1265C>A p.S422* | Nonsense Mutation (SNP) | VAF 22/62 reads (35%) | catalogued as COSV54327981; called by muse, mutect2, varscan2
- XDH | c.366G>A p.M122I | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1183778418, COSV65148197; called by muse, mutect2, varscan2
- XIRP1 | c.2548G>C p.D850H | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV61138042; called by muse, mutect2, varscan2
- ZBTB43 | c.1160G>C p.R387T | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65094705; called by muse, mutect2, varscan2
- ZC3H11A | c.1013C>T p.S338L | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV59745820; called by muse, mutect2, varscan2
- ZDHHC1 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.278); catalogued as rs1394740903, COSV62214915; called by muse, mutect2, varscan2
- ZDHHC3 | c.748G>C p.E250Q (on ENST00000424952 / NM_001135179.2; = p.E278Q on NM_016598.3) | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56101174, COSV56101743; called by muse, mutect2, varscan2
- ZFHX4 | c.4531G>C p.D1511H | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV50698588; called by muse, mutect2, varscan2
- ZFHX4 | c.9142G>C p.D3048H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370995988, COSV50584415, COSV50621902; called by mutect2, varscan2
- ZNF366 | c.384G>A p.M128I | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.395); catalogued as COSV59215051; called by muse, mutect2, varscan2
- ZNF420 | c.1307G>T p.R436L | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.286); catalogued as COSV100421359, COSV100421443; called by muse, mutect2
- ZNF532 | c.2569C>G p.L857V | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as rs764368512, COSV60172732; called by muse, mutect2, varscan2
- ZNF681 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as rs985744375, COSV68073883; called by muse, mutect2, varscan2
- ADAM10 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.01); called by muse, mutect2
- AZU1 | c.373_386del p.A125Qfs*98 | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | called by mutect2, varscan2
- DST | c.5786dup p.N1929Kfs*6 | Frame Shift Ins (INS) | VAF 20/62 reads (32%) | called by mutect2, pindel, varscan2
- SUPT20HL1 | c.1672C>T p.P558S | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS4 | c.2109C>A p.V703= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV63489770; called by muse, mutect2, varscan2
- ALPG | c.147G>A p.Q49= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV54965768; called by muse, mutect2, varscan2
- ANP32D | c.327G>A p.L109= | Silent (SNP) | VAF 45/127 reads (35%) | catalogued as COSV56979995; called by muse, mutect2, varscan2
- APBB1 | c.82C>T p.L28= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV54974885; called by muse, mutect2, varscan2
- ARHGEF11 | c.2295G>A p.K765= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as rs1447199624, COSV59353897; called by muse, mutect2, varscan2
- ATG2A | c.1095C>T p.F365= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV65966480; called by muse, mutect2, varscan2
- ATP6V1C1 | c.84G>A p.K28= | Silent (SNP) | VAF 26/78 reads (33%) | catalogued as COSV67777864; called by muse, mutect2, varscan2
- BAZ1A | c.141C>T p.C47= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV62409944; called by muse, mutect2, varscan2
- BORCS7 | c.51G>A p.V17= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs919618551, COSV54916624; called by muse, mutect2, varscan2
- C5orf15 | c.21G>A p.K7= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV51548332; called by muse, mutect2
- CADM1 | c.186C>T p.I62= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as COSV59008535; called by muse, mutect2, varscan2
- CARM1 | c.1515C>T p.L505= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as rs780775044, COSV53403299; called by muse, mutect2, varscan2
- CD27 | c.609C>T p.F203= | Silent (SNP) | VAF 22/144 reads (15%) | catalogued as rs772814106, COSV56946597; called by muse, mutect2, varscan2
- CELSR2 | c.2919C>T p.I973= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV54770153; called by muse, mutect2, varscan2
- CIT | c.5352C>T p.F1784= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as rs773246397, COSV55866543; called by muse, mutect2, varscan2
- DNAJC14 | c.996C>T p.L332= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs899464667, COSV57912764; called by muse, mutect2, varscan2
- DNMT1 | c.2695C>T p.L899= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV100532476; called by muse, mutect2
- DSG2 | c.2847C>A p.T949= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV55196879; called by muse, mutect2
- DTX1 | c.963G>A p.K321= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs748833568, COSV57496985; called by muse, varscan2
- DUSP2 | c.543C>T p.F181= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV56619707; called by muse, mutect2, varscan2
- EIPR1 | c.21G>A p.V7= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV60846948; called by muse, mutect2, varscan2
- EPHX4 | c.129C>A p.L43= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV64889396; called by muse, mutect2
- EPN1 | c.117C>A p.L39= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV50036987; called by muse, mutect2, varscan2
- FGD6 | c.2466G>A p.Q822= | Silent (SNP) | VAF 30/66 reads (45%) | catalogued as COSV59692476; called by muse, mutect2, varscan2
- FMOD | c.534G>A p.L178= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV100724513, COSV61609907; called by muse, mutect2, varscan2
- FSD2 | c.1515G>C p.L505= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as COSV58009622; called by muse, mutect2, varscan2
- GAA | c.2127C>G p.L709= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV56408225; called by muse, mutect2, varscan2
- GRK7 | c.933C>T p.G311= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as COSV53822520; called by muse, mutect2, varscan2
- HCN1 | c.636G>A p.V212= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as rs752579418, COSV57505838; called by muse, mutect2, varscan2
- HMG20A | c.513G>A p.Q171= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV60312246; called by muse, mutect2, varscan2
- HYDIN | c.15288G>A p.L5096= | Silent (SNP) | VAF 69/133 reads (52%) | catalogued as COSV66638552, COSV66641468; called by muse, mutect2, varscan2
- IFRD2 | c.1119C>T p.V373= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs782526953, COSV57113430; called by muse, mutect2, varscan2
- IMPDH2 | c.498C>G p.L166= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV58707775, COSV58708142; called by muse, mutect2, varscan2
- INSYN2A | c.177G>A p.Q59= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV54737245; called by muse, mutect2, varscan2
- KIAA1841 | c.1221C>G p.L407= | Silent (SNP) | VAF 44/151 reads (29%) | catalogued as COSV54374424; called by muse, mutect2, varscan2
- KIF13B | c.4032C>G p.L1344= | Silent (SNP) | VAF 25/43 reads (58%) | catalogued as COSV72954336; called by muse, mutect2, varscan2
- KRI1 | c.2111G>A p.*704= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV57264312; called by muse, mutect2, varscan2
- KRI1 | c.1986G>A p.V662= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV57265786; called by muse, varscan2
- KRI1 | c.1959G>A p.K653= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV57264475; called by muse, varscan2
- KRT10 | c.180G>A p.G60= | Silent (SNP) | VAF 40/100 reads (40%) | catalogued as rs772769268, COSV54089401; called by muse, mutect2, varscan2
- L3MBTL1 | c.876G>A p.K292= (on ENST00000418998 / NM_001377303.1; = p.K202= on NM_015478.7) | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV64228287; called by muse, mutect2, varscan2
- LSP1 | c.414G>A p.L138= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV61133773; called by muse, mutect2, varscan2
- LY9 | c.1860G>A p.E620= | Silent (SNP) | VAF 31/111 reads (28%) | catalogued as COSV54433536; called by muse, mutect2, varscan2
- MBTPS2 | c.579C>G p.L193= | Silent (SNP) | VAF 119/279 reads (43%) | catalogued as COSV63411088, COSV63411193; called by muse, mutect2, varscan2
- MLIP | c.771C>T p.L257= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV51428907; called by muse, mutect2, varscan2
- MYBPC3 | c.1734G>A p.L578= | Silent (SNP) | VAF 37/130 reads (28%) | catalogued as COSV57026274; called by muse, mutect2, varscan2
- MYH11 | c.3210G>A p.Q1070= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV55550590; called by muse, mutect2, varscan2
- NF2 | c.1470G>A p.P490= | Silent (SNP) | VAF 46/105 reads (44%) | catalogued as rs373442542, COSV58522862; ClinVar: likely benign; called by muse, mutect2, varscan2
- NOL8 | c.2850G>A p.T950= | Silent (SNP) | VAF 86/270 reads (32%) | catalogued as rs999199797, COSV100694547; called by muse, mutect2
- NPL | c.546C>T p.F182= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs758112340, COSV51123219; called by muse, mutect2, varscan2
- PAN3 | c.1329C>T p.F443= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV56702088; called by muse, mutect2, varscan2
- PCDH19 | c.390G>A p.P130= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as rs775408951, COSV55261540; called by muse, mutect2, varscan2
- PCDHGB1 | c.1722G>A p.V574= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV53933019; called by muse, mutect2, varscan2
- PCSK4 | c.483C>T p.I161= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs61735614; called by muse, varscan2
- PNKP | c.114G>A p.L38= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs1464406982, COSV59275521; called by muse, mutect2, varscan2
- POLA2 | c.1671G>A p.V557= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as COSV55480539; called by muse, mutect2, varscan2
- PRAMEF8 | c.1134C>T p.L378= | Silent (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- PRKCG | c.102G>A p.K34= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs760235967, COSV54726908; called by muse, varscan2
- PRUNE2 | c.3336C>T p.L1112= | Silent (SNP) | VAF 47/151 reads (31%) | catalogued as rs781010882, COSV65040714, COSV65043137; called by muse, mutect2, varscan2
- PSD4 | c.738C>T p.F246= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as rs761313374, COSV55526021, COSV99831060; called by muse, mutect2, varscan2
- RSF1 | c.2775G>C p.L925= | Silent (SNP) | VAF 32/114 reads (28%) | catalogued as COSV57839086; called by muse, mutect2, varscan2
- RYR3 | c.11733C>T p.F3911= (on ENST00000389232; = p.F3912= on NM_001036.6) | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV101212681, COSV66785646; called by muse, mutect2, varscan2
- SIGLEC1 | c.1581G>A p.V527= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs775386023, COSV52462259; called by muse, mutect2, varscan2
- SIVA1 | c.123G>A p.K41= | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as COSV100328509; called by muse, mutect2, varscan2
- SLC32A1 | c.150C>G p.L50= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV54146399; called by muse, mutect2, varscan2
- SLC6A12 | c.270C>T p.F90= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV62884837; called by muse, mutect2, varscan2
- SNIP1 | c.285G>A p.K95= | Silent (SNP) | VAF 75/189 reads (40%) | catalogued as COSV56166270; called by muse, mutect2, varscan2
- STK11IP | c.2151C>T p.L717= | Silent (SNP) | VAF 25/46 reads (54%) | catalogued as COSV55247994; called by muse, mutect2, varscan2
- STXBP5 | c.144C>T p.L48= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV51651056; called by muse, varscan2
- TMC3 | c.2091C>T p.I697= | Silent (SNP) | VAF 54/140 reads (39%) | catalogued as COSV63922847; called by muse, mutect2, varscan2
- TMEM132D | c.571C>T p.L191= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV70602127; called by muse, mutect2, varscan2
- TRAPPC6A | c.465G>A p.V155= (on ENST00000585934 / NM_001270891.2; = p.V169= on NM_024108.3) | Silent (SNP) | VAF 33/74 reads (45%) | catalogued as COSV50065131; called by muse, mutect2, varscan2
- UNC13C | c.1662C>T p.S554= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as COSV52864822; called by muse, mutect2, varscan2
- USP9X | c.1587C>T p.L529= | Silent (SNP) | VAF 47/144 reads (33%) | catalogued as COSV61068464; called by muse, mutect2, varscan2
- WNT2B | c.399C>T p.L133= (on ENST00000369684 / NM_024494.3; = p.L114= on NM_004185.4) | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV56673732; called by muse, mutect2, varscan2
- ZFHX3 | c.2022C>T p.P674= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV51715835; called by muse, mutect2, varscan2
- ZFHX4 | c.4287C>A p.L1429= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV50698298; called by muse, mutect2, varscan2
- ZKSCAN4 | c.1152C>T p.V384= | Silent (SNP) | VAF 43/117 reads (37%) | catalogued as rs774680877, COSV66023281; called by muse, mutect2, varscan2
- ZKSCAN8 | c.1446G>A p.R482= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV57638000; called by muse, mutect2, varscan2
- ZNF488 | c.687C>G p.L229= | Silent (SNP) | VAF 25/68 reads (37%) | called by muse, mutect2, varscan2
- CCNQP1 | n.589G>A | RNA (SNP) | VAF 17/95 reads (18%) | called by muse, mutect2, varscan2
- DCHS2 | n.4888C>G | RNA (SNP) | VAF 15/48 reads (31%) | catalogued as COSV100600928, COSV61770728, COSV61775894; called by muse, mutect2, varscan2
- LINC00303 | n.165G>C | RNA (SNP) | VAF 47/150 reads (31%) | called by muse, mutect2, varscan2
- MIR526A2 | n.35G>A | RNA (SNP) | VAF 56/138 reads (41%) | called by muse, mutect2, varscan2
- MSH5 | c.538-35G>A | Intron (SNP) | VAF 13/40 reads (33%) | catalogued as COSV65209424; called by muse, mutect2, varscan2
- OR2U1P | n.96C>G | RNA (SNP) | VAF 10/25 reads (40%) | called by muse, mutect2, varscan2
- PLPPR3 | c.658-33G>C | Intron (SNP) | VAF 15/54 reads (28%) | catalogued as COSV62459532; called by muse, mutect2, varscan2
- TBX2 | chr17:61412105 G>T | 3'Flank (SNP) | VAF 9/35 reads (26%) | called by muse, mutect2, varscan2
